Gene-level copy-number profile of tumor specimen BLGSP-71-06-00255-01B from CGCI case BLGSP-71-06-00255, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 15.3 years (5,573 days).
Specimen BLGSP-71-06-00255-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 442fd1dc-4834-463c-a74e-7fa1d5a8abb3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00255-12A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,790 have no estimate.
https://portal.gdc.cancer.gov/files/4f4415b5-7919-4247-86a9-d3c68c53957d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 3,633; copy number 2: 51,907; copy number 3: 3,172; copy number 4: 80; copy number 5: 6; copy number 6: 3; copy number 7: 2; copy number 8: 1; copy number 10: 2; copy number 11: 1; copy number 12: 2; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes (within-gene range 0–2): PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr2:88,861,886–89,027,731, 13 genes (within-gene range 0–2): IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11.
- chr21:13,654,073–13,724,274, 6 genes: AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,179,889–90,235,370, 5 genes, copy number 5: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr6:32,517,353–32,530,287, 1 gene, copy number 7: HLA-DRB5.
- chr7:63,449,819–63,456,687, 1 gene, copy number 11: ZNF734P.
- chr7:76,521,611–76,541,459, 4 genes, copy number 12–20: AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr9:64,439,346–64,440,180, 1 gene, copy number 8: SNX18P9.
- chr9:64,637,845–64,709,311, 2 genes, copy number 10: AL445665.1, BMS1P11.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5–6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:43,663,654–43,684,339, 1 gene, copy number 7 (within-gene range 2–7): AC011330.1.

Autosomal genes at a single copy (total copy number 1): 777. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
